Gene-level copy-number profile of tumor specimen C3N-03796-01 from CPTAC case C3N-03796, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 55.9 years (20,425 days).
Specimen C3N-03796-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8986d9ca-36c4-48ea-a0d9-3590ed9dd272.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03796-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/794b3d21-62c8-4deb-bc11-d9d1f14f85e1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 7,889; copy number 2: 45,982; copy number 3: 1,369; copy number 4: 3,361; copy number 5: 131; copy number 6: 5; copy number 7: 16; copy number 8: 36; copy number 9: 12; copy number 11: 2; copy number 13: 5; copy number 14: 16; copy number 16: 5; copy number 24: 46; copy number 36: 4; copy number 114: 26.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 304 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,626,787–204,728,106, 40 genes, copy number 24: ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2.
- chr5:28,548,135–36,688,334, 126 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr13:98,142,562–98,455,176, 2 genes, copy number 5 (within-gene range 2–5): FARP1, RNF113B.
- chr13:98,329,655–100,088,950, 46 genes, copy number 5–11: AL161896.1, FARP1-AS1, STK24, AL356423.1, STK24-AS1, NUS1P4, CYCSP35, CALM2P4, RN7SL60P, SLC15A1, DOCK9, DOCK9-AS1, AL161420.1, RPL7L1P12, RNU6-83P, DOCK9-DT, RPS6P23, UBAC2-AS1, GAPDHP22, UBAC2, RN7SKP9, H2AZP3, GPR18, GPR183, MIR623, HMGB3P4, CCR12P, TM9SF2, LINC01232, AL139035.1, LINC00449, LINC01039, CFL1P8, CLYBL, MIR4306, CLYBL-AS2, CLYBL-AS1, AL137139.1, AL137139.3, AL137139.2, ZIC5, ZIC2, LINC00554, NDUFA12P1, PCCA-DT, ASNSP3.
- chr13:108,207,439–110,129,136, 25 genes, copy number 9–16 (within-gene range 9–22): LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2.
- chr13:111,865,136–112,108,015, 6 genes, copy number 24: LINC00354, AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404.
- chr13:112,313,467–114,337,626, 59 genes, copy number 7–114: LINC01043, LINC01044, SPACA7, TUBGCP3, AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, RASA3, RASA3-IT1, CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.

Autosomal genes at a single copy (total copy number 1): 5,036. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
